RC case RC-B6VL — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3caffbf5-b123-486d-91cd-f4daacd069f5

Demographics
Sex at birth: male; Country of residence at enrollment: United States; Year of birth: 1948; Vital status: Dead; Days to death: 96 days; Year of death: 2022; Cause of death: Cancer Related.

Diagnoses (3)
1. Adult T-cell leukemia/lymphoma (HTLV-1 positive) (includes all variants) (the primary disease): ICD-O-3 morphology code: 9827/3; ICD-10 code: C84; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 74.1 years (27,074 days); Year of diagnosis: 2022; Method of diagnosis: Blood Draw; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): High-Intermediate Risk; Sites of involvement: Lymph node, NOS / Bone marrow / Peripheral blood.
   Pathology details: Bone marrow malignant cells: Yes; Greatest tumor dimension: 2.8 cm; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Clinical Trial Agent; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days; Days to treatment end: 25 days; Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Clinical trial indicator: Yes; Timepoint category: First Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Clinical Trial Agent; Initial disease status: Progressive Disease; Days to treatment start: 57 days; Treatment outcome: Treatment Ongoing; Clinical trial indicator: Yes; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; adjuvant Radiation Therapy, NOS, postoperative; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.
2. Progression (histology not recorded by GDC). Age at diagnosis: 74.2 years (27,114 days); Days to diagnosis: 40 days.
3. Progression (histology not recorded by GDC). Age at diagnosis: 74.4 years (27,170 days); Days to diagnosis: 96 days.

Follow-up (3 entries)
- Day 40 (progression): Progression or recurrence: Yes; Days to progression: 40 days.
- Day 67 (end of treatment course 1): Disease response: With Tumor.
- Day 96 (progression): Disease response: With Tumor; Progression or recurrence: Yes; Days to progression: 96 days; Imaging type: PET; Imaging result: Positive.

Molecular and laboratory tests
- Lactate Dehydrogenase 424 U/L [Blood test normal range upper: 250].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Diabetes, NOS / Hyperlipidemia / Hypertension / Benign Prostatic Hyperplasia.
- Timepoint category: Initial Diagnosis; Weight: 72.7 kg; Height: 169 cm; BMI: 25.5.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample RC-B6VL-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample RC-B6VL-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
